CPTAC case C3L-06338 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d97155ab-8817-4b53-b8db-7cf57528098e

Demographics
Sex at birth: male; Race: white; Year of birth: 1960; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 59.3 years (21,650 days); Year of diagnosis: 2019; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: TX; AJCC pathologic N: N3; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIC; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,845 days (5.1 years); Progression or recurrence: no; Days to last follow up: 1,845 days (5.1 years); Tumor focality: Multifocal; Ulceration indicator: No.
   Pathology details: Greatest tumor dimension: 4.5 cm; Lymph node involvement: Positive; Lymph nodes positive: 12; Lymph nodes tested: 12; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: Yes.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Immunotherapy (Including Vaccines) — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Days to follow up: 253 days; Disease response: Tumor Free; ECOG performance status: 1.
- Days to follow up: 617 days (1.7 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 994 days (2.7 years); Disease response: Tumor Free; ECOG performance status: 0.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 18; Cigarettes per day: 15; Tobacco smoking onset year: 1995; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 27.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-06338-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 229 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-06338-23: Section location: Lymph node; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3L-06338-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -7 days; Method of sample procurement: Blood Draw.
